Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A713, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A713-01A (Primary Tumor).

[page 1 of 6]
Pathology Result:

Specimen Collected Date: Specimen Received Date:
Order Number: Ordering Provider:
Medical Record Number Facility:
Status:

Accession #:
Pathologist:
Date of Procedure:
Date Received:
Date Reported:
Submitting Physician:
Location:

Addendum Present

CSCF ICD-3
Oligodendroglioma 9382/3
path
Glioma NOS 9384/3 NOS
CSCF
Site Brain, supratentorial
path Brain NOS C71.0
08/22/13 C71.9

FINAL DIAGNOSIS

A. POSTERIOR SUPERIOR MARGIN, BIOPSY:
--CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.

B. POSTERIOR SUPERIOR # 2, BIOPSY:
--CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.

C. ANTERIOR INFERIOR, BIOPSY:
--CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.

D. POSTERIOR INFERIOR, BIOPSY:
--CEREBRAL CORTEX AND MILDLY HYPERCELLULAR WHITE MATTER, NO SOLID TUMOR IDENTIFIED, SEE NOTE.

Note: Immunohistochemistry with antibody against ki-67 does not label cell nuclei within the parenchyma. Immunohistochemistry for CD20 is also non-reactive within parenchyma.

E. ANTERIOR INFERIOR MARGIN, BIOPSY:
--CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.
--SEPARATE FRAGMENTS OF VESSELS WITH PERIVASCULAR LYMPHOCYTE INFILTRATES, SEE NOTE.

Note: The lymphocyte infiltrates are predominately CD3 positive small lymphocytes, with a minority (approximately 30% of cells) labeling with antibody directed against CD20. Immunohistochemistry for CD30 is negative. Immunohistochemistry with antibody against desmin is non-reactive within the infiltrated small vessels. Immunohistochemistry with antibody against beta amyloid is negative within the vessels and shows amyloid plaques within the cortex. The perivascular infiltrates appear to be non-neoplastic.

Diagnostic Discrepancy		
Case is (circled):		

[page 2 of 6]
F. ANTERIOR INFERIOR, BIOPSY (#2):

--MINIMAL HYPERCELLULARITY, NO SOLID TUMOR IDENTIFIED.

G. ANTERIOR, BIOPSY:

--MILD HYPERCELLULARITY, NO SOLID TUMOR IDENTIFIED, SEE NOTE.

Note: Immunohistochemistries with antibodies directed against ki-67 and mutant IDH1 R132H do not highlight intraparenchymal cells.

H. TUMOR, EXCISION:

--INFILTRATING GLIOMA, WHO GRADE II, SEE NOTE.

Note: The tumor has cytologic features of oligodendroglial and astrocytic differentiation. Analysis for 1p and 19q deletions will be performed and the results reported in an addendum. Immunohistochemistry with antibody directed against ki-67 labels approximately 3% of nuclei in the most cellular areas of the tumor. Immunohistochemistry with antibody directed against mutant IDH1-R132H labels cells scattered within the more cellular tissue fragments. Immunohistochemistry for CD20 does not label intraparenchymal cells.

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's).
ASR's

have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at . The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. The assays were performed with appropriate positive and negative controls which stained appropriately.

[page 3 of 6]
Electronically Signed Out By [REDACTED]

Intraoperative Consultation:

Microscopic diagnosis:

FSAl, B, E: Cortex- no tumor present.

FS C: Mild glial hypercellularity.

FSD, F: Focal mild glial hypercellularity

Addendum/Procedures:

Addendum Date Ordered: [REDACTED]

Status: Signed Out

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Addendum Diagnosis

Date of Birth: [REDACTED]

Date of Receipt: [REDACTED]

Date of Report: [REDACTED]

Specimen: [REDACTED]

Date of Procedure Ordered: [REDACTED]

Status of Procedure: Signed Out

Procedure Result and Interpretation:

..... 1p/19q FISH RESULTS

RESULTS:

Chromosome 1p: Loss, eusomic

Chromosome 19q: Loss, eusomic

Quantitative FISH results:

1p36: 1.5

1q25: 2.3

1p36/1q25 ratio: 0.7

19q13: 1.6

19p13: 2.6

19q13/19p13 ratio: 0.6

SAMPLE SUBMITTED: Outside paraffin block [REDACTED]

INTERPRETATION:

1p loss: A majority of nuclei showed a relative reduction in 1p36 signals, consistent with allelic loss of the short arm of chromosome 1 (1p).

19q loss: A majority of nuclei showed a relative reduction in 19p13 signals, consistent with allelic loss of the long arm of chromosome 19 (19q).

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

[page 4 of 6]
Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger where there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneusomy for chromosome 1 and 19 may be associated with earlier recurrence.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13)

The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1p25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by [REDACTED] Institute. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Electronically Signed Out By [REDACTED]

Clinical History:
right frontal margin

Specimens Submitted As:
A: POSTERIOR SUPERIOR MARGIN
B: POSTERIOR SUPERIOR # 2
C: ANTERIOR INFERIOR
D: POSTERIOR INFERIOR
E: ANTERIOR INFERIOR MARGIN
F: ANTERIOR INFERIOR BIOPSY (#2)

[REDACTED]

[page 5 of 6]
G: ANTERIOR

H: TUMOR

Gross Description:

A: Received fresh for intra-operative consultation labelled with the patient's name, hospital number and "posterior superior margin" is a pink-tan fragment of soft tissue 0.4 x 0.3 x 0.2 cm. The specimen is submitted entirely for intra-operative diagnosis in 1 cassette.

B: Received fresh for intra-operative consultation labelled with the patient's name, hospital number and "posterior superior # 2" are pink-tan fragments of soft tissue aggregating to 0.5 x 0.3 x 0.2 cm. The specimen is submitted entirely for intra-operative diagnosis in 1 cassette.

C: Received fresh for intra-operative consultation, labeled with the patient's name, hospital number and "anterior inferior" is an irregular fragment of pink-tan soft tissue, 0.6 x 0.3 x 0.2 cm. The specimen is frozen entirely for intraoperative diagnosis. The specimen is submitted entirely in one cassette.

D: Received fresh for intra-operative consultation, labeled with the patient's name, hospital number and "posterior inferior" is an irregular fragment of pink-tan soft tissue, 0.7 x 0.3 x 0.5 cm. The specimen is frozen entirely for intraoperative diagnosis. The specimen is submitted entirely in one cassette.

[page 6 of 6]
E: Received fresh for intra-operative consultation, labeled with the patient's name, hospital number and "anterior inferior margin" is an irregular fragment of pink-tan soft tissue, 0.6 x 0.3 x 0.2 cm. The specimen is frozen entirely for intraoperative diagnosis. The specimen is submitted entirely in one cassette.

F: Received fresh for intra-operative consultation, labeled with the patient's name, hospital number and "anterior inferior biopsy (#2)" is an irregular fragment of pink-tan soft tissue, 0.7 x 0.5 x 0.3 cm. The specimen is frozen entirely for intraoperative diagnosis. The specimen is submitted entirely in one cassette.

G: Received fresh, labeled with the patient's name and number, and "A-anterior", is a segment of irregular, pink-tan soft tissue measuring 0.7 x 0.3 x 0.2 cm. Submitted in toto in one cassette.

H: Received fresh, labeled with the patient's name and number, and "B-tumor", are multiple segments of irregular, opaque white to pink-tan soft tissue measuring in aggregate 1.8 x 1.8 x 0.3 cm. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 774e179d-d8a5-4c48-938d-c8eb5e93a334 (TCGA-FG-A713.B44387B9-C120-4F55-87B5-484C23D6070C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).